TCGA case TCGA-44-2655 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/07b5663f-9a54-4462-b6c1-6fc8116b8714

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 65.3 years (23,854 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Intraductal carcinoma, noninfiltrating, NOS: ICD-O-3 morphology code: 8500/2; Tissue or organ of origin: Breast, NOS; Laterality: Left; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Breast.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 68.1 years (24,863 days); Days to diagnosis: 1,009 days (2.8 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Days to follow up: 575 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 667 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,324 days (3.6 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Prior to Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 73; FEV1/FVC before bronchodilator (%): 100; FEV1 before bronchodilator (% of reference): 91.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1958; Tobacco smoking quit year: 1988.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-44-2655-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.5; Intermediate dimension: 0.5; Shortest dimension: 0.3.
  Slide TCGA-44-2655-01A-01-TS1: Section location: Top; Percent tumor cells: 15; Percent tumor nuclei: 20; Percent normal cells: 85; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10.
  Slide TCGA-44-2655-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-44-2655-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-44-2655-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-44-2655-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; Pulmonary function test indicator: Yes.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 3, New neoplasm event types: New tumor event type: New Primary Tumor.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Ductal carcinoma in situ.
- Other malignancy form, Surgery: Other malignancy surgery type: Left Breast Mastectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,324 days; disease-specific survival: no event (censored), 1,324 days; disease-free interval: no event (censored), 1,324 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,009 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-44-2655-01A-01D-0944-01): tumor purity 0.33, ploidy 2.08, whole-genome doublings 0.
